Gene-level copy-number profile of tumor specimen TCGA-AO-A0JD-01A from TCGA case TCGA-AO-A0JD, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 59.8 years (21,831 days).
Specimen TCGA-AO-A0JD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.ce2e1bd2-6d7a-45d2-92ca-e2550974cfc8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AO-A0JD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 824 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c0bc37be-e3d9-4cf7-8610-6e22c48c38a8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 69; copy number 1: 522; copy number 2: 18,079; copy number 3: 7,161; copy number 4: 25,903; copy number 5: 2,381; copy number 6: 3,145; copy number 7: 878; copy number 8: 210; copy number 9: 609; copy number 10: 138; copy number 11: 27; copy number 12: 237; copy number 13: 42; copy number 14: 130; copy number 15: 185; copy number 16: 8; copy number 22: 74; copy number 36: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AO-A0JD-01A-11D-A059-01): tumor purity 0.62, ploidy 1.81, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 69 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:15,014,805–16,437,003, 65 genes (broad region; genes not listed).
- chr17:16,439,505–16,441,298, 4 genes: SNORD49B, SNORD49A, AC093484.4, SNORD65.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,451 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:46,541,806–46,941,855, 11 genes, copy number 9: RHOQ, RHOQ-AS1, PIGF, CRIPT, AC020604.1, LINC01118, SOCS5, LINC01119, AC016722.1, AC016722.2, MCFD2.
- chr2:46,956,615–46,956,888, 1 gene, copy number 9: AC093732.2.
- chr2:50,588,690–53,486,280, 25 genes, copy number 9–12: MTCO1P42, AC009234.1, MIR8485, AC007560.1, AC007682.1, AC007402.1, AC007402.2, KNOP1P3, CRYGGP, AC097463.1, CCDC12P1, AC079304.1, ZNF863P, Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431, AC010967.1, AC010967.2, AC010967.3, AC069157.2, AC069157.1.
- chr2:53,570,374–53,570,480, 1 gene, copy number 9: RNU6-997P.
- chr7:74,453,790–80,922,359, 140 genes, copy number 10–22 (within-gene range 4–22) (broad region; genes not listed).
- chr7:83,363,238–83,649,139, 1 gene, copy number 11 (within-gene range 4–11): SEMA3E.
- chr7:83,424,880–84,584,322, 5 genes, copy number 11: AC079987.1, RAD23BP2, SEMA3A, RPL7P30, AC003984.1.
- chr8:113,376,669–116,403,757, 14 genes, copy number 12–16: AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1.
- chr11:16,576,851–20,121,601, 99 genes, copy number 12–15 (within-gene range 7–15) (broad region; genes not listed).
- chr11:66,330,241–71,549,608, 195 genes, copy number 15–22 (broad region; genes not listed).
- chr11:92,748,732–94,621,421, 60 genes, copy number 14 (within-gene range 7–14): AP003718.1, LINC02746, AP003171.2, SNRPGP16, AP003171.1, MTNR1B, RPL26P31, AP002371.1, AP003072.4, SLC36A4, AP003072.2, AP003072.5, AP003072.3, AP003072.1, AP003969.1, AP003969.2, DEUP1, SMCO4, SRP14P2, RN7SL223P, AP003499.5, AP003499.4, AP003499.1, CEP295, Y_RNA, SCARNA9, AP003499.3, AP003499.2, AP001273.1, TAF1D, SNORA25, SNORA32, SNORD6, SNORA1, SNORA8, SNORD5, SNORA18, MIR1304, SNORA40, C11orf54, AP001273.2, MED17, VSTM5, Y_RNA, AP002795.1, HPRT1P3, HEPHL1, PHBP16, PANX1, AP002784.1, ARPC3P3, IZUMO1R, GPR83, MRE11, MIR548L, AP000786.1, ANKRD49, C11orf97, FUT4, PIWIL4.
- chr11:94,559,018–94,559,374, 1 gene, copy number 14: AP000943.3.
- chr11:94,706,431–96,343,195, 30 genes, copy number 13–36 (within-gene range 2–36): AMOTL1, AP002383.2, ST13P11, CWC15, KDM4D, AP002383.1, KDM4E, AP002383.5, AP002383.3, AP002383.4, KDM4F, AP001264.1, SRSF8, ENDOD1, BUD13P1, AP000787.2, AP000787.1, SESN3, AP000787.3, AP001790.1, AP000820.2, AP000820.1, AP001877.1, FAM76B, CEP57, MTMR2, RNA5SP345, AP000870.1, MAML2, AP000779.1.
- chr11:99,020,949–100,358,885, 2 genes, copy number 15–22 (within-gene range 2–22): CNTN5, RN7SKP53.
- chr11:102,396,332–103,479,863, 33 genes, copy number 14 (within-gene range 2–14): TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1.
- chr14:57,563,920–57,982,194, 1 gene, copy number 9 (within-gene range 5–9): SLC35F4.
- chr14:57,629,841–58,648,321, 26 genes, copy number 9: AL136520.1, RN7SKP99, AL049838.1, ARMH4, AL121579.2, UBA52P3, RN7SL598P, AL121579.1, ACTR10, PSMA3, AL132989.1, PSMA3-AS1, HMGB1P14, LINC00216, RNU6-341P, ARID4A, AL139021.2, TOMM20L, AL139021.1, TIMM9, KIAA0586, Y_RNA, HSBP1P1, HNRNPCP1, RPL9P5, DACT1.
- chr14:58,794,654–58,828,176, 2 genes, copy number 9: AL049873.1, AL049873.2.
- chr14:74,941,834–80,455,469, 114 genes, copy number 9–14 (broad region; genes not listed).
- chr14:86,283,243–89,619,149, 42 genes, copy number 10 (within-gene range 4–10): AL161753.1, LINC02309, LINC01148, AL358292.1, AL352955.1, AL157688.1, LINC02296, AL135746.1, LINC02330, AL359237.1, AL136501.1, GALC, SHLD2P2, RNU6-835P, GPR65, AL157955.1, LINC01147, LINC01146, AL133279.2, AL133279.3, AL133279.1, KCNK10, SPATA7, PTPN21, AL162171.2, RNU4-22P, AL162171.1, ZC3H14, AL162171.3, EML5, AL121768.1, RNU4-92P, TTC8, Y_RNA, AL137785.1, MPPE1P1, FOXN3, AL138478.1, CAP2P1, AL357093.2, AL357093.1, AL356805.1.
- chr14:89,417,354–89,419,793, 1 gene, copy number 10: FOXN3-AS1.
- chr14:91,965,991–93,188,463, 20 genes, copy number 10 (within-gene range 6–10): TRIP11, AL049872.1, ATXN3, NDUFB1, CPSF2, AL133240.1, RNU6-366P, AL133240.2, SLC24A4, RIN3, LGMN, GOLGA5, LINC02833, LINC02287, CHGA, ITPK1, ITPK1-AS1, CYB5AP3, MOAP1, TMEM251.
- chr14:94,960,277–95,335,757, 10 genes, copy number 10: LINC02279, AL390254.1, DICER1, MIR3173, DICER1-AS1, CLMN, AL356017.1, AL117187.1, AL117187.2, LINC02292.
- chr14:97,110,416–97,789,256, 9 genes, copy number 11: AL049833.2, AL049833.1, LINC02304, AL158800.1, LINC02325, LINC02291, AL163872.1, LINC02312, AL355097.1.
- chr14:99,158,416–106,875,071, 519 genes, copy number 9–14 (broad region; genes not listed).
- chr17:61,590,421–63,696,305, 64 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr18:64,041,555–64,423,601, 1 gene, copy number 11 (within-gene range 7–11): LINC01924.
- chr18:64,181,314–66,069,647, 11 genes, copy number 11 (within-gene range 7–11): LINC01538, AC027506.1, AC090348.1, AC007948.1, AC007631.1, LINC01916, AC090358.1, CDH7, AC023394.2, AC023394.1, PRPF19P1.
- chr18:67,375,133–68,114,878, 13 genes, copy number 13: AC091042.1, AC110597.1, DSEL, AC110597.3, AC114689.3, AC022662.1, AC022655.1, FAM32DP, AC114689.1, LINC01903, AC114689.2, AC100844.1, AC068112.1.

Autosomal genes at a single copy (total copy number 1): 522. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
